Gene-level copy-number profile of tumor specimen BLGSP-71-06-00007-01B from CGCI case BLGSP-71-06-00007, project CGCI-BLGSP (Burkitt Lymphoma Genome Sequencing Project). Sex at birth: male; Vital status: Dead; Primary diagnosis: Burkitt lymphoma, NOS (Includes all variants); Tissue or organ of origin: Hematopoietic system, NOS; Age at diagnosis: 6.9 years (2,538 days).
Specimen BLGSP-71-06-00007-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ac9147a1-64ee-4516-b222-64920836388c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator BLGSP-71-06-00007-99A (granulocytes); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,739 have no estimate.
https://portal.gdc.cancer.gov/files/a768e579-28e9-41fb-a148-dc67bf402c61

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 606; copy number 1: 2,419; copy number 2: 53,804; copy number 3: 1,968; copy number 4: 60; copy number 5: 18; copy number 6: 8; copy number 10: 1.

Homozygous deletions (total copy number 0; autosomes only): 94 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:88,857,161–89,245,596, 34 genes (within-gene range 0–3): IGKC, IGKJ5, IGKJ1, IGKV4-1, IGKV5-2, IGKV7-3, PGBD4P5, IGKV2-4, IGKV1-5, IGKV1-6, IGKV3-7, IGKV1-8, IGKV1-9, IGKV2-10, IGKV3-11, IGKV1-12, IGKV1-13, IGKV2-14, IGKV3-15, IGKV1-16, IGKV1-17, IGKV2-18, IGKV2-19, IGKV6-21, IGKV1-22, IGKV2-23, IGKV2-24, IGKV3-25, IGKV2-26, AC244255.1, IGKV1-27, IGKV2-28, IGKV2-29, IGKV2-30.
- chr14:105,851,705–106,108,464, 59 genes (within-gene range 0–2): IGHM, MIR4539, MIR4507, MIR4538, MIR4537, IGHJ6, IGHJ3P, IGHJ5, IGHJ4, IGHJ3, IGHJ2P, IGHJ2, IGHJ1, IGHD7-27, IGHJ1P, IGHD1-26, IGHD6-25, IGHD5-24, IGHD4-23, IGHD3-22, IGHD2-21, AC246787.2, IGHD1-20, IGHD6-19, IGHD5-18, IGHD4-17, IGHD3-16, IGHD2-15, IGHD1-14, IGHD6-13, IGHD5-12, IGHD4-11, IGHD3-10, IGHD3-9, IGHD2-8, IGHD1-7, IGHD6-6, IGHD5-5, IGHD4-4, IGHD3-3, IGHD2-2, FAM30A, IGHD1-1, IGHV6-1, IGHVII-1-1, ADAM6, AC246787.1, IGHV1-2, IGHVIII-2-1, IGHV1-3, IGHV4-4, IGHV7-4-1, IGHV2-5, IGHVIII-5-1, IGHVIII-5-2, IGHV3-6, IGHV3-7, IGHV3-64D, IGHV5-10-1.
- chr14:106,170,749–106,171,052, 1 gene (within-gene range 0–2): IGHVIII-16-1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:18,333,726–18,419,273, 4 genes, copy number 6: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6.
- chr15:32,175,247–32,500,346, 18 genes, copy number 5: Y_RNA, AC068448.1, AC139426.3, RNU6-18P, AC139426.1, AC139426.2, DNM1P31, GOLGA8K, RN7SL185P, AC135983.1, ULK4P1, U8, DNM1P32, GOLGA8O, RN7SL539P, AC135983.5, AC135983.4, AC135983.3.
- chr16:90,102,271–90,178,344, 1 gene, copy number 6 (within-gene range 4–10): FAM157C.
- chr16:90,110,574–90,222,851, 4 genes, copy number 6–10: AC133919.2, RNU6-355P, LINC02193, CICP25.

Autosomal genes at a single copy (total copy number 1): 75. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
